Gene-level copy-number profile of tumor specimen TCGA-L1-A7W4-01A from TCGA case TCGA-L1-A7W4, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 48.8 years (17,821 days).
Specimen TCGA-L1-A7W4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.3d42a413-174e-465a-b440-7429226931ba.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L1-A7W4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS.
https://portal.gdc.cancer.gov/files/9285c820-1899-40c5-95a2-a713bd68a5c8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 11,660; copy number 2: 41,329; copy number 3: 6,046; copy number 4: 64; copy number 5: 288; copy number 6: 386; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:51,028,394–54,599,493, 33 genes (within-gene range 0–1): SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3, AC016383.3, AC016383.2, AC016383.1, DCC, AC011155.1, VN1R76P, MIR4528, LINC01917, LINC01919, RPL29P32, AC090666.1, MBD2, SNORA37, AC093462.1, POLI, STARD6, C18orf54, SNRPGP2, CUPIN1P, AC090897.1, AC091135.1, AC091135.2, DYNAP.
- chr19:10,960,932–11,079,426, 4 genes (within-gene range 0–1): SMARCA4, AC011442.1, RN7SL192P, AC006127.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 675 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:224,294,930–227,164,453, 21 genes, copy number 5–8 (within-gene range 1–8): AC008072.1, FAM124B, AC073052.1, CUL3, ANKRD49P1, CCDC195, DOCK10, MIR4439, NYAP2, AC016717.1, AC016717.2, AC016717.3, AC068138.1, AC062015.1, MIR5702, IRS1, AC010735.2, AC010735.1, RHBDD1, AC073149.1, COL4A4.
- chr2:227,979,955–231,926,396, 87 genes, copy number 5 (broad region; genes not listed).
- chr2:231,978,488–232,015,720, 1 gene, copy number 5: AC019130.1.
- chr8:90,198,389–95,156,685, 98 genes, copy number 5 (broad region; genes not listed).
- chr8:95,206,876–95,403,894, 3 genes, copy number 5: LINC01298, C8orf37, AC024995.1.
- chr8:124,450,820–145,066,685, 386 genes, copy number 6 (broad region; genes not listed).
- chr19:38,244,035–38,292,615, 1 gene, copy number 5 (within-gene range 3–5): SPINT2.
- chr19:38,289,151–39,555,356, 78 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,660. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
